Somatic mutation profile of tumor specimen TCGA-TN-A7HI-01A (aliquot TCGA-TN-A7HI-01A-11D-A34J-08) from TCGA case TCGA-TN-A7HI, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 56.6 years (20,666 days).
Specimen TCGA-TN-A7HI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca6c1c01-0539-4c4f-9182-03fc91db0257.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TN-A7HI-10A (Blood Derived Normal), aliquot TCGA-TN-A7HI-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdf15ade-c5bb-4ac4-ab61-dce58cd17054

The open-access MAF lists 55 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 9, Nonsense Mutation 4, Splice Site 3, 3'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTC | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs66656800, CM062969, CM930524, CM941118, CS930849, COSV50001616; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 42/130 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RNF213 | c.12037G>A p.D4013N | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.405); catalogued as rs397514563, CM1111820, COSV100300800; ClinVar: likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- ABCA6 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.791); catalogued as COSV52639835, COSV99445733; called by muse, mutect2, varscan2
- ADAM2 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs764580418, COSV55869849; called by muse, mutect2, varscan2
- ADCY2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 62/314 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444489998, COSV57859329; called by muse, mutect2, varscan2
- ADRA1D | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1399257265, COSV101063050; called by muse, mutect2, varscan2
- ANKRD50 | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV101538987, COSV72385269; called by muse, mutect2, varscan2
- CAPN1 | c.2101A>G p.T701A | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV99658724; called by muse, mutect2, varscan2
- CD47 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs770928049, COSV100790127; called by muse, mutect2, varscan2
- DOCK1 | c.3520G>A p.V1174I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs758548443, COSV99730401; called by muse, mutect2, varscan2
- DUSP14 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1402474801; called by muse, mutect2, varscan2
- EPM2AIP1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV99212500; called by muse, mutect2, varscan2
- GPR37L1 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.023); catalogued as rs1335072527, COSV100938561; called by muse, mutect2, varscan2
- GRM6 | c.1757C>A p.A586E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51432129; called by muse, mutect2, varscan2
- IL9 | c.199C>G p.P67A | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as COSV99192436; called by muse, mutect2
- IQGAP3 | c.4336C>T p.R1446* | Nonsense Mutation (SNP) | VAF 8/13 reads (62%) | catalogued as rs759473769, COSV63252275; called by muse, varscan2
- KCNB2 | c.539G>T p.W180L | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV101578830; called by muse, mutect2, varscan2
- KCNH3 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs757600141, COSV57792132; called by muse, mutect2, varscan2
- LRRC7 | c.3924G>A p.W1308* (on ENST00000651989 / NM_001370785.2; = p.W1275* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 48/150 reads (32%) | catalogued as COSV50507053; called by muse, mutect2, varscan2
- MROH2B | c.2552C>T p.T851I | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101270737; called by muse, mutect2, varscan2
- NAA15 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99649645; called by muse, mutect2, varscan2
- OR52N4 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100421697; called by muse, mutect2, varscan2
- PCDH15 | c.3739G>C p.D1247H | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV100222184; called by muse, mutect2, varscan2
- PDLIM2 | c.770C>T p.T257M (on ENST00000397760; = p.T507M on NM_021630.6) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs368145484, COSV56132713; called by muse, mutect2, varscan2
- PRDX2 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV100040226; called by muse, mutect2, varscan2
- PREX1 | c.4205C>T p.T1402M | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs757617983, COSV64248165; called by muse, mutect2, varscan2
- RBL1 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs1351601949, COSV100727098; called by muse, mutect2, varscan2
- SCN4A | c.4456G>A p.G1486S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV101438524; called by muse, mutect2, varscan2
- SDC3 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752559236, COSV59579634; called by muse, mutect2, varscan2
- SFMBT2 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780440731, COSV62806193; called by muse, mutect2, varscan2
- SLC1A7 | c.136-1G>A p.X46_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV101019655; called by muse, mutect2, varscan2
- TGM2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs746351550, COSV100821502; called by muse, mutect2, varscan2
- TRPV5 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as rs762806939, COSV99520625; called by muse, mutect2, varscan2
- TTI2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.005); catalogued as rs139842383; called by muse, mutect2, varscan2
- VLDLR | c.1066+1G>A p.X356_splice | Splice Site (SNP) | VAF 38/165 reads (23%) | catalogued as rs774744705, COSV66073256; called by muse, mutect2, varscan2
- VSTM4 | c.636G>A p.V212= | Splice Region (SNP) | VAF 24/108 reads (22%) | catalogued as rs765343409, COSV100251811; called by muse, mutect2, varscan2
- WNK2 | c.2770G>A p.V924I | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs755613061, COSV99943027; called by muse, mutect2, varscan2
- ZFHX4 | c.9076A>T p.I3026F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99263812; called by muse, mutect2
- ZFYVE26 | c.4208G>A p.G1403D | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100720502; called by muse, mutect2, varscan2
- ZNF395 | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.568); catalogued as COSV100733996; called by muse, mutect2, varscan2
- ZNF781 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as rs542777466, COSV62200253; called by muse, mutect2, varscan2
- CACNA1H | c.5029_5031del p.F1677del | In Frame Del (DEL) | VAF 8/26 reads (31%) | called by pindel, varscan2
- SPEF2 | c.3802-7_3802del p.X1268_splice | Splice Site (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel
- UMODL1 | c.2068A>C p.T690P (on ENST00000408910 / NM_001004416.2; = p.T818P on NM_173568.3) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- AGO1 | c.1467C>T p.F489= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as COSV64596785; called by muse, mutect2, varscan2
- CYTH3 | c.1092G>A p.P364= (on ENST00000396741; = p.P363= on NM_004227.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs778048265, COSV100084597; called by muse, mutect2, varscan2
- MDN1 | c.4089C>T p.I1363= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as rs565438867, COSV101021467; called by muse, mutect2, varscan2
- MICOS10 | c.12G>T p.S4= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100503355; called by muse, mutect2, varscan2
- OTOGL | c.1764A>T p.T588= (on ENST00000547103; = p.T579= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1163197870, COSV101509351; called by muse, mutect2, varscan2
- RASGRP3 | c.1524C>T p.C508= (on ENST00000402538 / NM_001349975.2; = p.C507= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs761479290, COSV67823448; called by muse, mutect2, varscan2
- RGS20 | c.693C>T p.P231= (on ENST00000297313 / NM_170587.4; = p.P84= on NM_003702.4) | Silent (SNP) | VAF 30/209 reads (14%) | catalogued as COSV99392196; called by muse, mutect2, varscan2
- TBX2 | c.987C>T p.P329= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99538934; called by muse, mutect2, varscan2
- WASHC2A | c.4005G>A p.L1335= | Silent (SNP) | VAF 70/290 reads (24%) | catalogued as COSV50953380; called by muse, mutect2, varscan2
- SMIM12 | chr1:34855239 C>T | 3'Flank (SNP) | VAF 25/70 reads (36%) | catalogued as COSV101315072; called by muse, mutect2, varscan2
